ALCHEMIST case ALCH-B2MQ — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/77f8e5e8-29b8-49a0-a935-c30df0110fe8

Demographics
Sex at birth: male.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: Age at diagnosis: 74.5 years (27,220 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B2MQ-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B2MQ-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B2MQ-TTP1-B-1-0-S1: Section location: Top; Percent tumor cells: 53; Percent tumor nuclei: 70; Percent normal cells: 5; Percent necrosis: 3; Percent stromal cells: 39; Percent lymphocyte infiltration: 22; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
